Surgical pathology report (de-identified scan), TCGA case TCGA-WD-A7RX, project TCGA-CHOL (Cholangiocarcinoma), tissue source site  Emory University, specimen TCGA-WD-A7RX-01A (Primary Tumor).

[page 1 of 4]
Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

ICD-O-3

Cholangiocarcinoma 8160/3

Site Liver C22.0

9/12/13

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Copy To Phys:

DOB:

Gender:

F

(Age:

Acc #:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LIVER, LESION, BIOPSY (A1FS):
- CHOLANGIOCARCINOMA.

B. LIVER, BIOPSY (B1FS):
- CIRRHOSIS.
- NO CARCINOMA IS IDENTIFIED.

C. LIVER, RIGHT HEPATECTOMY:
- CHOLANGIOCARCINOMA, INTRAHEPATIC (ADENOCARCINOMA OF PANCREATICOBILIARY TYPE IN LIVER).
- THE TUMOR IS MULTIFOCAL WITH THE LARGEST FOCUS, 3.3 CM.
- TUMOR FOCALLY EXTENDS TO WITHIN 0.1 CM OF PARENCHYMAL MARGIN OF RESECTION.
- TUMOR SUPERFICIALLY INVADES INTO THE ADVENTITIA OF A LARGE CALIBER VEIN IN THE HEPATIC PARENCHYMA, BUT THE LUMEN OF THE VEIN IS FREE OF CARCINOMA.
- TUMOR ABUTS THE CAPSULE OF THE LIVER.
- SEE SYNOPTIC REPORT.

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
Path Reports

* Final Report *

- UNINVOLVED LIVER SHOWS EVOLVING CIRRHOSIS.

Comment

Immunohistochemical stains performed excludes the presence of focal hepatocellular differentiation. The malignant cells are positive for CK7 (bile ductular marker) and are negative for hepatocellular marker hep-par1, glypican 3, arginase. CD10 and poly-CEA show focal positivity, but canalicular pattern formation is not convincing. CD56 is negative. This pattern of staining is consistent with the above diagnosis.

A trichrome stain demonstrates bridging fibrosis that would have qualified as at least stage 3 of 4.

Electronically Signed by

Assisted by:

Synoptic Worksheet

C. Liver-right lobe:

Clinical History:	Cirrhosis
Specimen:	Liver
Procedure:	Other: RIGHT LOBE
Tumor Focality:	Multiple: RIGHT LOBE
Histologic Type:	Cholangiocarcinoma
Histologic Grade:	GII: Moderately differentiated
Tumor Size:	Greatest dimension: 3.3 cm
	Additional Dimension: 2.8 cm
	Additional Dimension: 2.7 cm
Microscopic Tumor Extension:	Tumor confined to hepatic parenchyma
Hepatic Parenchymal Margin:	Uninvolved by invasive carcinoma. Distance of invasive carcinoma from closest margin: 1 mm
	Margin uninvolved by invasive carcinoma: PARENCHYMAL
Bile Duct Margin:	Cannot be assessed
Other Margin:	Margin: VASCULAR
	Uninvolved by invasive carcinoma
Tumor Growth Pattern:	Mass-forming
Venous (Major Vessel) Invasion (V):	Indeterminate
Small Vessel Invasion (L):	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2b: Multiple tumors, with or without vascular invasion
Regional Lymph Nodes (pN):	pNX: Cannot be assessed
	Number of nodes examined: 0
	Number of nodes involved: 0
Distant Metastasis (pM):	Not applicable

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Path Reports

* Final Report *

Clinical History

Exploratory laparotomy and right hepatectomy. Liver tumor.

Specimen(s) Received

A: Liver lesion
B: Liver, biopsy
C: Liver-right lobe

Gross Description

Specimen A is received fresh for intraoperative consultation, identified with patient's name, medical record number and further designated as "liver lesion". The specimen consists of two fragments of soft tissue measuring 0.7 x 0.5 x 0.3 cm in aggregate. The entire specimen is submitted for frozen section diagnosis and contents of cryostat are transferred in cassette A1FS.

Specimen B is received fresh for intraoperative consultation, identified with patient's name, medical record number and further designated as "liver biopsy". The specimen consists of three fragments of core needle biopsy measuring 0.2 to 1.8 cm in length. The entire specimen is submitted for frozen section diagnosis and contents of cryostat are transferred in cassette B1FS.

Part C is received fresh, labeled with the patient's name, medical record number and "liver, right lobe." The specimen consists of a liver lobe measuring 14.5 x 14.0 x 7.0 cm and weighing 514 grams. The parenchymal margin measures 10.0 x 9.0 cm. There is a firm vaguely lobulated and infiltrative appearing mass measuring 3.3 x 2.8 x 2.7 cm abutting a large caliber vein, abutting the parenchymal margin of resection, and abutting the liver capsule. There is a similar mass measuring 0.6 cm in diameter located approximately 1.0 cm from the dominant mass and 0.5 cm from the parenchymal margin of resection. No other lesions are identified. The parenchymal margin of resection is inked black. Tissue is submitted to
Representative sections are submitted as described below.

CASSETTE SUMMARY:

C1:	Stapled vascular margin of resection in parenchymal margin
C2:	Large caliber vein margin of resection
C3:	Mass abutting parenchymal margin of resection
C4:	Additional mass abutting parenchymal margin of resection
C5:	Mass in relation to large caliber vein
C6:	Mass in relation to uninvolved liver
C7:	Smaller mass
C8:	Representative uninvolved liver
C9:	Mass in relation to liver capsule

Intraoperative Consult Diagnosis

A1FS: LIVER, (FROZEN SECTION): CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by
at and the specimen was received at

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Path Reports

* Final Report *

B1FS: LIVER BIOPSY, (FROZEN SECTION): FOCAL BRIDGING FIBROSIS.

Frozen section results were communicated to the surgical team and were repeated back by
at . and the specimen was received at

Pathologist:

Microscopic Description

Microscopic examination performed.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER:

Some of the above tests may use Class I ASRs. These tests were developed and their performance characteristics determined by

They have not been cleared or approved by the Federal Drug Administration (FDA). The FDA does not require these tests
to go through premarket FDA review. These tests are used for clinical purposes, and should not be regarded as investigational or for research.
laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity
clinical laboratory testing.

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file 152a24f0-b5c3-49f2-9fb1-c5c589a2cc91 (TCGA-WD-A7RX.9D3F4AEF-2F52-4035-AFFC-A5AD2A31EE5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).